Surgical pathology report (de-identified scan), TCGA case TCGA-QT-A5XN, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of North Carolina, specimen TCGA-QT-A5XN-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

Adrenal gland, left, laparoscopic adrenalectomy
- Adrenal cortical adenoma, 3.0 cm diameter, without extracapsular extension, surgical margins not involved.
- Pheochromocytoma, 5.0 cm diameter, without extracapsular extension, surgical margins not involved.

Clinical History:

-year-old female with left adrenal mass.

Gross Description:

Received is one appropriately labeled container, additionally labeled "left adrenal mass" and holds a disrupted adrenal gland (6.0 x 1.4 x 0.2 cm) with two masses identified arising from opposite ends of the adrenal gland. The first mass (mass #1: 3.0 x 3.0 x 2.0 cm) is well-circumscribed with a soft, orange/yellow chalky cut surface. No areas of hemorrhage or necrosis are grossly appreciated. The mass appears to expand and compress the adjacent adrenal cortex and grossly abuts the blue inked external surface. The second mass (mass #2: 5.0 x 5.0 x 4.0 cm) is a poorly circumscribed homogeneous mass with a partially solid partially cystic (0.7 to 1.5 cm cyst diameter) cut surface. The majority of the mass is dusky red and hemorrhagic with occasional firmer white randomly dispersed patches. No definitive areas of necrosis are identified. The mass appears to arise from the adrenal medulla and is compressing adjacent adrenal parenchyma. Mass #2 grossly abuts the blue-inked external margin. Representative sections are submitted per block summary.

Block Summary:

A1-A3 - Representative sections of mass #1
A4-A8 - Represents section of mass #2

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed by Dr.

EAD 0-3
Pheochromocytoma NAS
8700/0
Site ^{1st} Adrenal gland,
medulla C74.1
Coff Adrenal gland NAS
C74.9
JW 4/13/13

[page 2 of 2]
Sections of the 3 cm cortical nodule show bland cytology reminiscent of zona fasciculata. No extracapsular extension is noted.

The 5cm central nodule is cytologically similar to adrenal medulla. Immunostains to clarify lineage were performed, and show reactivity for synaptophysin and chromogranin, with peripheral cortical reactivity for inhibin. This immunophenotype supports a diagnosis of pheochromocytoma. No extracapsular extension is noted.

Malignant behavior not stated/not staged.
BCR

Source: NCI Genomic Data Commons file 3b9867c1-6404-4825-b49a-a3917c63742a (TCGA-QT-A5XN.F0603AB8-922C-4B85-A745-95FABEBBE230.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).